Somatic mutation profile of tumor specimen MP2PRT-PAVWLM-TMP1-A (aliquot MP2PRT-PAVWLM-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVWLM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,575 days).
Specimen MP2PRT-PAVWLM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d971d514-9ebb-4f64-a549-8dc3bfc7c6eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWLM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWLM-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7064343-053d-4fe5-9111-ca83cdbf5d76

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 77/206 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 146/472 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs201466383, COSV99794238; called by muse, mutect2, varscan2
- ADGRL2 | c.3203T>C p.L1068P (on ENST00000370717 / NM_001366005.1; = p.L1055P on NM_012302.4) | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54657805; called by muse, mutect2, varscan2
- DAP | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 65/180 reads (36%) | catalogued as rs767625403; called by muse, varscan2
- LRP1 | c.12397G>A p.A4133T | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.207); catalogued as COSV54504064; called by muse, varscan2
- PRMT8 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV54212391, COSV54220255; called by muse, mutect2
- SIPA1L1 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs146893925; called by muse, mutect2
- SLC29A4 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 143/331 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs766220634; called by muse, mutect2, varscan2
- ZFYVE28 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52108072; called by muse, mutect2
- KMT2D | c.13014dup p.T4339Hfs*33 | Frame Shift Ins (INS) | VAF 172/519 reads (33%) | called by mutect2, pindel, varscan2
- PEG3 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 126/304 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- C4orf54 | c.2397C>T p.R799= | Silent (SNP) | VAF 134/438 reads (31%) | catalogued as rs970896692; called by muse, mutect2, varscan2
- HTR3A | c.24G>A p.A8= | Silent (SNP) | VAF 128/287 reads (45%) | catalogued as rs779864146; called by muse, mutect2, varscan2
- KRT6B | c.1509C>T p.V503= | Silent (SNP) | VAF 136/359 reads (38%) | catalogued as rs145254155; called by muse, mutect2, varscan2
- MCF2L | c.1974C>T p.A658= (on ENST00000375608; = p.A626= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as rs774744432; called by muse, mutect2, varscan2
- OR2V1 | chr5:181130194 G>A | 5'Flank (SNP) | VAF 114/272 reads (42%) | called by muse, mutect2, varscan2
